Somatic mutation profile of tumor specimen 0DGZFG from CCDI case PBBUBH, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 4.2 years (1,528 days).
Specimen 0DGZFG: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 15e59d8f-961d-4faa-8763-ac7c320a79da.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DGYZ3 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fbc598e1-dab6-4993-a8b4-4a5b6cf9b3a0

The open-access MAF lists 7 somatic variants for this specimen: 4 protein-altering or splice-affecting, 3 silent.
By variant classification: Silent 3, Missense Mutation 3, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GRK3 | c.1421G>A p.R474Q | Missense Mutation (SNP) | VAF 279/580 reads (48%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.993); catalogued as rs761438308; called by muse, mutect2, varscan2
- OR5F1 | c.418G>A p.V140I | Missense Mutation (SNP) | VAF 327/735 reads (44%) | SIFT tolerated (0.21); PolyPhen benign (0.025); catalogued as COSV53545625; called by muse, mutect2, varscan2
- USP32 | c.1900C>T p.R634W | Missense Mutation (SNP) | VAF 130/4440 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1182476634; called by muse, mutect2
- PTCH1 | c.1403_1437del p.A468Vfs*17 | Frame Shift Del (DEL) | VAF 171/259 reads (66%) | called by mutect2, pindel, varscan2
- ANKFY1 | c.2385C>T p.N795= (on ENST00000341657 / NM_001330063.2; = p.N796= on NM_016376.5) | Silent (SNP) | VAF 247/585 reads (42%) | catalogued as rs369709173; called by muse, mutect2, varscan2
- KDM4C | c.378C>T p.N126= | Silent (SNP) | VAF 200/617 reads (32%) | called by muse, mutect2, varscan2
- SLC34A2 | c.1266C>T p.V422= | Silent (SNP) | VAF 270/531 reads (51%) | catalogued as rs547233904; called by muse, mutect2, varscan2
